Gene-level copy-number profile of tumor specimen TCGA-14-3476-01B from TCGA case TCGA-14-3476, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.4 years (27,172 days).
Specimen TCGA-14-3476-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8fcb6cc0-ab33-4e69-88df-c3cae742c6ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-3476-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate.
https://portal.gdc.cancer.gov/files/8cdde20d-8ad1-4572-a03e-cabdc3a2bc4f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 7,837; copy number 2: 45,606; copy number 3: 6,249; copy number 4: 13; copy number 5: 67; copy number 7: 14.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,086,459–5,992,473, 10 genes (within-gene range 0–1): LINC02782, AL139823.1, Z98259.3, Z98259.2, Z98259.1, Z97988.2, AL365255.1, Z97988.1, MIR4689, NPHP4.
- chr1:50,437,028–50,960,267, 1 gene (within-gene range 0–2): FAF1.
- chr1:50,780,340–50,974,634, 3 genes: PHBP12, MRPS6P2, CDKN2C.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,214,672, 12 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 81 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,105,706–14,398,983, 14 genes, copy number 7 (within-gene range 1–7): MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1.
- chr14:22,147,995–22,518,871, 67 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,456. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
